Gene-level copy-number profile of tumor specimen TCGA-GU-A764-01A from TCGA case TCGA-GU-A764, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.6 years (24,343 days).
Specimen TCGA-GU-A764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.88d6a486-9b17-4745-be51-948446d9e249.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A764-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40f5247b-8840-45a1-9176-efb5d455cf8e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,039; copy number 2: 22,726; copy number 3: 21,301; copy number 4: 8,339; copy number 5: 2,856; copy number 6: 1,498; copy number 7: 1,001; copy number 8: 225; copy number 9: 107; copy number 10: 15; copy number 11: 217; copy number 12: 9; copy number 13: 105; copy number 15: 43; copy number 16: 58; copy number 17: 34; copy number 18: 12; copy number 20: 32; copy number 21: 58; copy number 24: 104; copy number 33: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A764-01A-11D-A34T-01): tumor purity 0.23, ploidy 2.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,044 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–153,923,360, 345 genes, copy number 7–13 (within-gene range 3–13) (broad region; genes not listed).
- chr1:158,254,424–163,509,595, 212 genes, copy number 7–11 (broad region; genes not listed).
- chr1:164,769,116–169,630,193, 114 genes, copy number 9–15 (broad region; genes not listed).
- chr1:169,690,665–169,711,702, 1 gene, copy number 9 (within-gene range 4–9): SELL.
- chr2:60,998,752–64,252,859, 74 genes, copy number 7–33 (broad region; genes not listed).
- chr2:65,158,662–65,158,860, 1 gene, copy number 16: SNORA74.
- chr6:19,290,319–24,426,194, 56 genes, copy number 8–20: AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2.
- chr9:214,854–465,259, 1 gene, copy number 11 (within-gene range 2–11): DOCK8.
- chr9:452,492–11,436,244, 146 genes, copy number 11–21 (broad region; genes not listed).
- chr10:53,802,771–55,627,942, 6 genes, copy number 17 (within-gene range 3–17): PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1.
- chr11:87,718,354–90,915,052, 85 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr12:220,621–1,936,574, 34 genes, copy number 8 (within-gene range 1–8): SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940.
- chr12:5,432,108–8,138,548, 130 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:24,566,964–26,833,194, 51 genes, copy number 7–13: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr19:50,649,445–51,108,409, 40 genes, copy number 7: C19orf81, SHANK1, CLEC11A, GPR32P1, GPR32, AC010325.1, ACP4, AC010325.2, C19orf48, SNORD88B, SNORD88A, SNORD88C, AC010325.3, LINC01869, KLK1, KLK15, AC011523.1, KLK3, KLK2, KLKP1, KLK4, PPIAP59, KLK5, AC011483.2, KLK6, AC011483.3, AC011483.1, KLK7, KLK8, AC011473.4, KLK9, KLK10, AC011473.2, KLK11, KLK12, AC011473.3, AC011473.1, KLK13, KLK14, CTU1.
- chr19:54,236,592–57,167,485, 200 genes, copy number 8–24 (within-gene range 3–24) (broad region; genes not listed).
- chr20:87,250–24,666,616, 489 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:49,812,713–49,892,242, 1 gene, copy number 7 (within-gene range 3–7): SLC9A8.
- chr20:49,903,391–52,670,578, 58 genes, copy number 7 (within-gene range 5–7): SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4.

Autosomal genes at a single copy (total copy number 1): 1,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
